Somatic mutation profile of tumor specimen BA2559D (aliquot aq-BA2559D) from BEATAML1.0 case 2329, project BEATAML1.0-COHORT (Functional Genomic Landscape of Acute Myeloid Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Acute monoblastic and monocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 42.7 years (15,589 days).
Specimen BA2559D: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 924f8167-1e4e-4304-9d3a-b27ad26768d2.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen BA2624D (Solid Tissue Normal), aliquot aq-BA2624D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2ef409e0-1a1f-4b08-beae-7686855913f7

The open-access MAF lists 2 somatic variants for this specimen: 1 protein-altering or splice-affecting, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: 3'UTR 1, Missense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PTBP1 | c.458C>A p.A153E | Missense Mutation (SNP) | VAF 4/44 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.497); catalogued as rs1295072402; called by muse, mutect2
- PTDSS1 | c.*143C>A | 3'UTR (SNP) | VAF 3/31 reads (10%) | called by muse, mutect2
